Gene-level copy-number profile of tumor specimen TCGA-A6-5667-01A from TCGA case TCGA-A6-5667, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 40.4 years (14,756 days).
Specimen TCGA-A6-5667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.b3ff4b38-9925-4f31-a3a9-39fd4718c993.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-5667-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f65d2e5-002b-4ebf-a8ca-face75927161

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 16,266; copy number 3: 23,789; copy number 4: 16,571; copy number 5: 27; copy number 6: 361; copy number 7: 1,714; copy number 8: 46; copy number 9: 584; copy number 10: 244; copy number 11: 143; copy number 12: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-5667-01A-21D-1717-01): tumor purity 0.69, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,798 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:87,152,409–98,401,090, 182 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:46,579,213–145,066,685, 1,532 genes, copy number 7 (broad region; genes not listed).
- chr20:19,212,642–19,722,926, 1 gene, copy number 9 (within-gene range 2–9): SLC24A3.
- chr20:19,693,209–64,313,132, 1,083 genes, copy number 8–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
